Somatic mutation profile of tumor specimen TCGA-ZC-AAAF-01A (aliquot TCGA-ZC-AAAF-01A-11D-A428-09) from TCGA case TCGA-ZC-AAAF, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 74.2 years (27,099 days).
Specimen TCGA-ZC-AAAF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bfc5f17-388e-4f14-9f34-db3b98f89e8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZC-AAAF-10A (Blood Derived Normal), aliquot TCGA-ZC-AAAF-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ee1b867-bef3-49db-8937-96486b242a70

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 46/410 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- KCNK16 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs376531453; called by mutect2, varscan2
- PCDHA9 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782455446, COSV65326479; called by muse, mutect2, varscan2
- TP73 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs771056792, COSV100601101, COSV100601679; called by muse, mutect2, varscan2
- ADAR | c.1285C>A p.P429T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.261); called by muse, mutect2
- ANO6 | c.1363T>A p.C455S | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ATP2B2 | c.2032A>G p.N678D (on ENST00000352432; = p.N644D on NM_001683.5) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- DBX1 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX40 | c.974-1G>A p.X325_splice | Splice Site (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- ETNPPL | c.172C>A p.H58N | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- INTS9 | c.1788G>C p.Q596H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- MYBPC1 | c.256C>A p.L86I (on ENST00000550270 / NM_206820.2; = p.L111I on NM_002465.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCNT | c.9296A>T p.K3099M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PCYT1B | c.972_976del p.T325Efs*40 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- ADGRE1 | c.1524G>A p.K508= | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- ANKRD12 | c.3945C>T p.V1315= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV50841357; called by muse, mutect2
- CYP4F12 | c.1119C>T p.D373= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs1402563038; called by muse, mutect2, varscan2
- PCDHA10 | c.1446C>T p.D482= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV56541619; called by muse, mutect2, varscan2
- PKHD1L1 | c.3789T>C p.Y1263= | Silent (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- SCN1A | c.5052C>T p.Y1684= (on ENST00000303395 / NM_001202435.3; = p.Y1673= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs1433806086, CM113358, COSV57679391; called by muse, mutect2, varscan2
